Somatic mutation profile of tumor specimen HCM-CSHL-0239-C18-01A (aliquot HCM-CSHL-0239-C18-01A-21D-A78J-36) from HCMI case HCM-CSHL-0239-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,072 days).
Specimen HCM-CSHL-0239-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32ee1884-cf04-4757-a9ef-d84f4397b84e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0239-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0239-C18-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0224c4a5-2e7e-4866-8740-49ece10d7734

The open-access MAF lists 138 somatic variants for this specimen: 90 protein-altering or splice-affecting, 32 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 32, Intron 7, Nonsense Mutation 5, 3'UTR 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 3, RNA 3, Splice Site 3, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 110/292 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as rs933815442; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>T p.A939V (on ENST00000506720 / NM_001322402.2; = p.A871V on NM_015236.6) | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs777017067, COSV101546801, COSV72230433; called by muse, mutect2, varscan2
- ALCAM | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262196322; called by muse, mutect2, varscan2
- ALOX12B | c.1362+2T>C p.X454_splice | Splice Site (SNP) | VAF 21/364 reads (6%) | catalogued as COSV59875300; called by muse, mutect2
- APC | c.3942del p.R1314Sfs*7 | Frame Shift Del (DEL) | VAF 89/410 reads (22%) | catalogued as COSV57371145; called by mutect2, pindel, varscan2
- ARHGAP31 | c.348G>A p.T116= | Splice Region (SNP) | VAF 20/169 reads (12%) | catalogued as rs749601853, COSV99956942; called by muse, mutect2, varscan2
- ARHGEF4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759872047, COSV58123575, COSV58129852; called by muse, mutect2, varscan2
- BRINP2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV64175026, COSV64181319; called by muse, mutect2, varscan2
- CASZ1 | c.5106C>G p.D1702E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs770293169, COSV100985043; called by muse, varscan2
- CDH2 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs768097198; called by muse, mutect2, varscan2
- CES1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV100828742; called by muse, mutect2
- CFAP46 | c.7930G>A p.G2644S | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1342524342; called by muse, mutect2
- COQ10B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs776608625, COSV55836205; called by muse, mutect2
- DYNC1I1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs376275541, COSV61461083; called by muse, mutect2, varscan2
- EFCAB6 | c.3625G>A p.V1209I | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs533490129, COSV53076235; called by muse, mutect2, varscan2
- EPB41L1 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 350/1339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs779328780, COSV52438381; called by muse, mutect2, varscan2
- EVC2 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs140316127; called by muse, mutect2, varscan2
- FBXL7 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs1341792515, COSV61645247; called by muse, mutect2, varscan2
- FH | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1303488878, COSV100844968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN4 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961855111; called by muse, mutect2, varscan2
- HNRNPCL2 | c.610dup p.I204Nfs*2 | Frame Shift Ins (INS) | VAF 52/411 reads (13%) | catalogued as rs766966451; called by mutect2, pindel, varscan2
- IFNA1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs777221783, COSV52806429; called by mutect2, varscan2
- KHDC1 | c.233C>T p.T78M (on ENST00000370384 / NM_001251874.2; = p.T5M on NM_030568.5) | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs774462256, COSV100001740; called by muse, mutect2, varscan2
- KIF2B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260059640, COSV52129098; called by muse, mutect2, varscan2
- MCM3AP | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs190933622, COSV52439372; called by muse, mutect2, varscan2
- MEOX2 | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100012552; called by muse, varscan2
- NFATC1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs758037357, COSV53701290; called by muse, mutect2, varscan2
- PAX7 | c.1164C>A p.S388R | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV64749566; called by muse, mutect2, varscan2
- PCDHA12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV56497066; called by muse, mutect2, varscan2
- POM121L12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs749141757, COSV68692580, COSV68693810; called by muse, mutect2, varscan2
- RELN | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 69/527 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.963); catalogued as rs372887562; called by muse, mutect2, varscan2
- RFX6 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as rs1353404589, COSV60587723; called by muse, mutect2, varscan2
- RIMS2 | c.1522C>T p.R508C (on ENST00000666250 / NM_001348490.2; = p.R316C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376615886; called by muse, mutect2, varscan2
- RSPO1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749070990, COSV62974774; called by muse, mutect2, varscan2
- SMARCA2 | c.4750G>C p.G1584R | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs887291939; called by muse, mutect2, varscan2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 38/70 reads (54%) | catalogued as rs781940283; called by mutect2, varscan2
- SSTR3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766144463; called by muse, mutect2, varscan2
- TENM4 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.782); catalogued as rs572476843; called by muse, mutect2
- TRIM48 | c.383G>C p.C128S | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101338238; called by muse, mutect2, varscan2
- TRPS1 | c.1643G>A p.R548H (on ENST00000220888 / NM_001330599.2; = p.R561H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); catalogued as rs371005211; called by muse, mutect2
- TTLL4 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs758954798, COSV51436788; called by muse, mutect2, varscan2
- XKR6 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as rs748823161; called by muse, mutect2, varscan2
- ADGRV1 | c.14518G>C p.V4840L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, varscan2
- C4orf17 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CBFA2T2 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 65/684 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.422); called by muse, mutect2
- CEP250 | c.1956G>C p.K652N | Missense Mutation (SNP) | VAF 71/1261 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2
- CLEC2B | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN6 | c.419_428del p.V140Afs*56 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- CPA1 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CSMD3 | c.8470G>C p.V2824L (on ENST00000297405 / NM_001363185.1; = p.V2655L on NM_052900.3) | Missense Mutation (SNP) | VAF 66/495 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTPS2 | c.1549C>A p.H517N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP51A1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DOCK10 | c.2322A>T p.K774N | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK10 | c.2320A>T p.K774* | Nonsense Mutation (SNP) | VAF 5/122 reads (4%) | called by muse, mutect2
- DSP | c.7972G>A p.G2658S | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT8D2 | c.991T>A p.W331R | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HEPHL1 | c.1717-1G>T p.X573_splice | Splice Site (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2
- HOXB6 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.8714G>A p.C2905Y (on ENST00000360013 / NM_001024660.4; = p.C1208Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KCNH7 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- KCTD3 | c.2327C>G p.S776* | Nonsense Mutation (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- KPNA3 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- LPIN1 | c.2295-3C>A | Splice Region (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- MBTPS1 | c.3060A>C p.Q1020H | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NCOA6 | c.4127T>G p.V1376G | Missense Mutation (SNP) | VAF 40/642 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.086); called by muse, mutect2
- NETO2 | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIC | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NKRF | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PADI3 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PDZD2 | c.4956del p.L1652Ffs*20 | Frame Shift Del (DEL) | VAF 52/220 reads (24%) | called by mutect2, pindel, varscan2
- PGBD2 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PITRM1 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PLK4 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- POLR3A | c.2486C>A p.A829D | Missense Mutation (SNP) | VAF 81/558 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PREX1 | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 50/802 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKG2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- RASSF6 | c.449C>G p.P150R (on ENST00000342081 / NM_201431.2; = p.P118R on NM_177532.5) | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RFC4 | c.779_780del p.K260Sfs*12 | Frame Shift Del (DEL) | VAF 28/288 reads (10%) | called by mutect2, pindel
- SLCO1A2 | c.1204T>A p.Y402N | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYCP2 | c.2772A>G p.K924= | Splice Region (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- TMEM176A | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- UNC80 | c.2749C>A p.H917N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- YPEL1 | c.17dup p.S7Vfs*28 | Frame Shift Ins (INS) | VAF 44/283 reads (16%) | called by mutect2, pindel, varscan2
- ZAN | c.8414-2A>C p.X2805_splice | Splice Site (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- ZFHX2 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZFHX4 | c.8896A>G p.I2966V | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF157 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- ZNF804A | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- ZNF850 | c.2671C>T p.H891Y | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.11244G>A p.L3748= | Silent (SNP) | VAF 184/487 reads (38%) | called by muse, mutect2, varscan2
- AJM1 | c.414G>A p.A138= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1227562744; called by muse, mutect2, varscan2
- BOD1L1 | c.684G>A p.K228= | Silent (SNP) | VAF 41/402 reads (10%) | called by muse, mutect2, varscan2
- CCDC92 | c.864C>T p.H288= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs750311604; called by muse, mutect2, varscan2
- CELA3A | c.348G>T p.S116= | Silent (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- CRB1 | c.549C>T p.C183= | Silent (SNP) | VAF 53/229 reads (23%) | catalogued as rs756544059; called by muse, mutect2, varscan2
- CRB2 | c.576G>A p.P192= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as rs1040869162; called by muse, mutect2, varscan2
- DDR2 | c.666A>C p.G222= | Silent (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- DIP2B | c.249T>C p.S83= | Silent (SNP) | VAF 36/276 reads (13%) | catalogued as rs745727513; called by muse, mutect2, varscan2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 57/725 reads (8%) | catalogued as rs141057778; called by muse, mutect2
- EBAG9 | c.69G>A p.K23= | Silent (SNP) | VAF 30/548 reads (5%) | catalogued as COSV61753283; called by muse, mutect2
- EIPR1 | c.612G>A p.A204= | Silent (SNP) | VAF 85/319 reads (27%) | catalogued as rs754801494; called by muse, mutect2, varscan2
- EPHB6 | c.309G>A p.A103= | Silent (SNP) | VAF 174/542 reads (32%) | catalogued as rs370537878; called by muse, varscan2
- FAT4 | c.13755C>A p.I4585= | Silent (SNP) | VAF 55/321 reads (17%) | catalogued as COSV100629211, COSV58691432; called by muse, mutect2, varscan2
- FUT7 | c.57C>T p.A19= | Silent (SNP) | VAF 184/604 reads (30%) | catalogued as rs757216024; called by muse, mutect2, varscan2
- GPAT2 | c.1905C>T p.G635= | Silent (SNP) | VAF 61/198 reads (31%) | catalogued as COSV100853219; called by muse, mutect2, varscan2
- HES3 | c.213C>T p.S71= | Silent (SNP) | VAF 50/284 reads (18%) | catalogued as rs750211535; called by muse, varscan2
- HOXD1 | c.18G>A p.E6= | Silent (SNP) | VAF 55/459 reads (12%) | catalogued as rs756995034; called by muse, mutect2, varscan2
- IFIT3 | c.96G>A p.R32= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- KANSL2 | c.351C>T p.C117= | Silent (SNP) | VAF 36/276 reads (13%) | called by muse, mutect2, varscan2
- KLRF1 | c.117C>A p.I39= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as COSV54380299; called by muse, mutect2, varscan2
- MSI1 | c.276T>G p.P92= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- NAV3 | c.3591A>G p.T1197= | Silent (SNP) | VAF 42/293 reads (14%) | catalogued as rs1167459934; called by muse, mutect2, varscan2
- NKX1-1 | c.552G>A p.A184= | Silent (SNP) | VAF 28/423 reads (7%) | called by muse, mutect2
- NRP2 | c.1845C>T p.T615= | Silent (SNP) | VAF 71/411 reads (17%) | catalogued as rs867179644; called by muse, mutect2, varscan2
- PAX3 | c.141C>T p.N47= | Silent (SNP) | VAF 70/566 reads (12%) | catalogued as CM961088; called by muse, mutect2, varscan2
- RANBP17 | c.1887T>G p.L629= | Silent (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- TENM4 | c.1779C>T p.G593= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs1355154660; called by muse, mutect2, varscan2
- THBD | c.1503C>T p.P501= | Silent (SNP) | VAF 64/519 reads (12%) | catalogued as rs373402912; called by muse, mutect2, varscan2
- TMEM129 | c.390C>G p.L130= | Silent (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 154/510 reads (30%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- TUBB | c.708C>T p.V236= | Silent (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2, varscan2
- AC104078.1 | n.315G>C | RNA (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- ADGRB2 | c.*49T>C | 3'UTR (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505964 G>C | 5'Flank (SNP) | VAF 10/21 reads (48%) | catalogued as rs1284458281; called by muse, mutect2, varscan2
- DCAF17 | c.*2287G>A | 3'UTR (SNP) | VAF 37/156 reads (24%) | catalogued as rs1171932777; called by muse, mutect2, varscan2
- FER1L4 | n.3633T>C | RNA (SNP) | VAF 44/1062 reads (4%) | catalogued as rs1336885603; called by muse, mutect2
- JAKMIP3 | c.*292G>A | 3'UTR (SNP) | VAF 57/205 reads (28%) | catalogued as rs114837050; called by muse, mutect2, varscan2
- LHX1 | c.675+14G>A | Intron (SNP) | VAF 25/204 reads (12%) | catalogued as rs1186726122; called by muse, mutect2, varscan2
- NR1D2 | c.1146+623G>T | Intron (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- PAX6 | c.1184-45C>T | Intron (SNP) | VAF 29/190 reads (15%) | catalogued as rs1433241521; called by mutect2, varscan2
- PTN | c.-201G>T | 5'UTR (SNP) | VAF 49/209 reads (23%) | called by muse, mutect2, varscan2
- SGIP1 | c.*39G>A | 3'UTR (SNP) | VAF 9/92 reads (10%) | catalogued as rs765036166; called by muse, mutect2, varscan2
- SLC66A1L | n.558A>G | RNA (SNP) | VAF 25/197 reads (13%) | catalogued as COSV101456719; called by muse, mutect2, varscan2
- TMEM116 | c.-199+1481G>T | Intron (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- TMEM199 | c.376-10_376-9insG | Intron (INS) | VAF 26/210 reads (12%) | called by mutect2, pindel, varscan2
- USH1C | c.1284+7677G>A | Intron (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- ZMAT4 | c.103-19039T>G | Intron (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
